HCMI case HCM-EXPT-1073-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/0f28235c-b4bb-451b-8b89-6092a231f0f9

Demographics
Sex at birth: female; Year of birth: 1941.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 76.4 years (27,907 days); Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1073-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1073-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 48; Percent tumor nuclei: 70; Percent normal cells: 8; Percent necrosis: 2; Percent stromal cells: 42; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1073-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 28; Percent tumor nuclei: 45; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 57; Percent lymphocyte infiltration: 45; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
